Gene-level copy-number profile of tumor specimen C3N-01261-03 from CPTAC case C3N-01261, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 68.0 years (24,825 days).
Specimen C3N-01261-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f6867227-6788-42d0-b7bc-496210136451.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01261-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/25117db8-234e-4317-990d-7925b1a8c429

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,014; copy number 3: 42; copy number 4: 54,236; copy number 5: 28; copy number 6: 586; copy number 9: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes, copy number 9: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
